Surgical pathology report (de-identified scan), TCGA case TCGA-DW-7963, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-7963-01B (Primary Tumor).

[page 1 of 4]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Surgical Pathology Report

PATIENT:	MRN:
ACCOUNT#:	RECEIVED DATE:
DOB:	PROCEDURE DATE:
AGE:	SIGN-OUT DATE:
ATTENDING:	LOCATION:
REQUESTING:	ROOM:
CONTACT NO:	
COPIES TO:	

DIAGNOSIS:

- Soft tissue, right paracaval mass, resection (1FS): Lymph node, no tumor seen (0/1).
- Lymph node, right hilar, resection (2FS): Nerve and ganglia.
- Right renal mass, deep margin, resection: Renal parenchyma, no tumor seen.
- Kidney, right, mass, partial nephrectomy: Renal cell carcinoma, papillary Type 1, with extensive necrosis and hemorrhage. Inked margin of resection is negative for tumor. See Note.

5.

NOTE:

Surgical Pathology Cancer Case Summary (Checklist)

KIDNEY: Nephrectomy, Partial

Procedure (Note D)

Partial nephrectomy

Specimen Laterality

Right

Tumor Size (largest tumor if multiple)

Greatest dimension: 4.6 cm

*Additional dimensions: 4.1 x 1.3 cm

Tumor Focality

Unifocal

Macroscopic Extent of Tumor (select all that apply) (Note E)

Tumor limited to kidney

ICD-0-3
carcinoma, papillary renal cell
8260/3
Site: kidney, nos *C64.9*
ju
10/24/12

Histologic Type (Note A)

Papillary renal cell carcinoma

Patient Identification

Surgical Pathology Report

File In

[page 2 of 4]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Name: --

MRN:

Date of Report:

Sarcomatoid Features (Note B)

Not identified

*Tumor Necrosis (any amount)

*Present

Histologic Grade (Fuhrman Nuclear Grade) (Note C)

G2: Nuclei slightly irregular, approximately 15 μ m; nucleoli evident

Microscopic Tumor Extension (select all that apply)

Tumor limited to kidney

Margins (select all that apply) (Note F)

Margins uninvolved by invasive carcinoma

Pathologic Staging (pTNM) (Note G)

TNM Descriptors (required only if applicable) (select all that apply)

pT1b: Tumor more than 4 cm but not more than 7 cm in greatest dimension, limited to the kidney

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Distant Metastasis (pM)

Not applicable

Pathologic Findings in Nonneoplastic Kidney (select all that apply) (Note H)

Insufficient tissue (partial nephrectomy specimen with <5 mm of adjacent nonneoplastic kidney)

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief Clinical History: Right

Renal Mass, Gross Hematuria Specimen Taken For Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: Right Renal Mas Post-Operative Diagnosis:

same Operative Findings: Solitary right renal mass with invasion into collecting system, suspicious lymph node in renal hilum

SPECIMENS SUBMITTED: 1. ROUTINE + 4FS, Right paracaval mass (1FS)

2. ROUTINE + 3FS, Right hilar lymph node (2FS)

Patient Identification

Surgical Pathology Report

File in

Page 2 of 4

[page 3 of 4]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Name:

MRN:

Date of Report:

3. KIDNEY, Right rena mass deep margin

4. KIDNEY, Right mass

INTRAOPERATIVE CONSULTATION:

1FS "Right paracaval mass"

1FS diagnosis: Lymph node, no tumor seen.

2FS "Right hilar lymph node"

2FS diagnosis: Ganglia.

The frozen sections are diagnosed by

GROSS DESCRIPTION: Received 4 containers labeled with the patient's name, medical record number, and further specified as follows:

1. "Right paracaval mass 1FS" consists of a tan-pink soft tissue fragment measuring 0.3 x 0.3 x 0.3 cm. The specimen is totally frozen as 1FS. In Surgical Pathology, the specimen received matches the above description. The frozen sample is transferred to an orange cassette labeled : 1FS for permanent processing.
2. "Right hilar lymph node" consists of a tan-pink soft tissue fragment measuring 0.8 x 0.4 x 0.3 cm. The specimen is totally frozen as 2FS. In Surgical Pathology, the specimen received matches the above description. The frozen sample is transferred to an orange cassette labeled 2FS for permanent processing.
3. "Right renal mass deep margin" consists of 2 yellow-tan soft tissue fragments measuring 0.5 x 0.3 x 0.1 cm and 0.7 x 0.2 x 0.1 cm. They are entirely submitted in a white cassette labeled : #3 for permanent processing.
4. "Right kidney mass" is a partial nephrectomy specimen measuring 6.5 x 4.8 x 4.5 cm. There is a shiny surface consistent with serosa measuring 5.1 x 4.5 cm on one side, fat below and kidney parenchyma on surface. Per surgeon, L... the area between the fat and the kidney parenchyma separated in the trochanter bag revealing the pseudocapsule. There was also a small nick measuring up to 0.3 cm on the surface. The specimen is inked in black. The black ink came in contact with the pseudocapsule which was repainted in green. The specimen is bisected revealing a nodule with yellow hemorrhagic cut surface and with hard and soft areas. The nodule measures 4.6 x 1.3 x 4.1 cm. The tumor is at 0.1 cm from the closest surgical margin. About 30% of the tissue is procured for Pictures are taken. In Surgical Pathology, the specimen received matches the above description. The specimen is serially sectioned. The tumor with pseudocapsule is submitted in white cassette for permanent

Patient Identification

Surgical Pathology Report

File in

Page 3 of 4

[page 4 of 4]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Name: _____
MRN: _____

Accession No.: _____
Date of Report: _____

processing. Another seven representative sections are submitted in white cassettes labeled 4B-4I for permanent processing. The procurement was performed by

Gross description dictated by

No consultants

HPA Discrepancy		☒
Case is (re)staged		☒

10/26/12

Patient Identification	Surgical Pathology Report
File in	Page 4 of 4

Source: NCI Genomic Data Commons file 500baae5-06e1-4e21-a36c-c03e69195171 (TCGA-DW-7963.D8DA2A5D-2CE1-4B6C-8EE6-DE5760EE24C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).